Somatic mutation profile of tumor specimen TCGA-CG-4474-01A (aliquot TCGA-CG-4474-01A-02D-1158-08) from TCGA case TCGA-CG-4474, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 67.6 years (24,686 days).
Specimen TCGA-CG-4474-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c9e29bd-08e7-4c73-91ba-03a5571f0bcf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-4474-10A (Blood Derived Normal), aliquot TCGA-CG-4474-10A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/119ff8c8-4c57-45c5-9cff-26f7665ae02b

The open-access MAF lists 94 somatic variants for this specimen: 73 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 19, Frame Shift Del 5, Nonsense Mutation 5, Splice Site 3, In Frame Ins 1, RNA 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSS2 | c.1063T>A p.C355S | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV53626741; called by muse, mutect2
- ACTB | c.185G>C p.R62T | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.746); catalogued as COSV59319374, COSV59320008; called by muse, mutect2, varscan2
- ACTN2 | c.37G>A p.V13M | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV63976988; called by muse, mutect2, varscan2
- ADAM23 | c.1140G>T p.K380N | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.42); catalogued as COSV52223016; called by muse, mutect2, varscan2
- ADAMTS3 | c.2086A>T p.N696Y | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54397211; called by muse, mutect2, varscan2
- ARID2 | c.3286C>T p.Q1096* | Nonsense Mutation (SNP) | VAF 27/129 reads (21%) | catalogued as COSV57610169; called by muse, mutect2, varscan2
- ATP6V0A1 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52876029; called by muse, mutect2, varscan2
- CCDC138 | c.1328C>T p.S443L | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs367747465, COSV54570005; called by muse, mutect2, varscan2
- CDH1 | c.563T>A p.V188D | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55737233; called by muse, mutect2, varscan2
- CENPW | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 17/85 reads (20%) | catalogued as COSV64177043; called by muse, mutect2, varscan2
- CHRNB3 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs185338940; called by muse, mutect2, varscan2
- CPNE9 | c.777C>A p.N259K | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as rs746197434, COSV56069246; called by muse, mutect2
- CYSLTR1 | c.55G>C p.D19H | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64819341, COSV64820796; called by muse, mutect2, varscan2
- DMD | c.7143G>T p.E2381D | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV58932132; called by muse, mutect2, varscan2
- EIF3M | c.345G>C p.K115N | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as COSV60073016, COSV60073233; called by muse, mutect2, varscan2
- ELAPOR2 | c.2614G>A p.A872T (on ENST00000450689 / NM_001142749.3; = p.A705T on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.198); catalogued as rs1180072250, COSV51887553; called by muse, mutect2, varscan2
- EVC2 | c.3896A>T p.K1299I | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV60398412; called by muse, mutect2, varscan2
- FGA | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 54/251 reads (22%) | catalogued as rs776817952, COSV57398625; called by muse, mutect2, varscan2
- FGFR2 | c.1109C>A p.T370K | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.82); PolyPhen benign (0.021); catalogued as COSV100335611, COSV60651897, COSV60653993; called by muse, mutect2, varscan2
- FLG | c.545A>C p.K182T | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.053); catalogued as rs773896823, COSV64245110; called by muse, mutect2, varscan2
- FLT4 | c.3594C>G p.S1198R | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV56116437; called by muse, mutect2, varscan2
- G6PD | c.473G>T p.C158F | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM104025, COSV63703846; called by muse, mutect2, varscan2
- GALM | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 63/268 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as rs536207322, COSV55370426, COSV55371004; called by muse, mutect2, varscan2
- GOLGA3 | c.29G>A p.G10D | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.177); catalogued as rs1403465920, COSV52638033; called by muse, mutect2, varscan2
- HAPLN3 | c.433C>A p.R145S | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV62085313, COSV62085847; called by muse, mutect2, varscan2
- HDGFL2 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56684124; called by muse, mutect2, varscan2
- HGF | c.541C>T p.R181* | Nonsense Mutation (SNP) | VAF 15/122 reads (12%) | catalogued as COSV55946925; called by muse, mutect2, varscan2
- HOMER3 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs574022526, COSV55357377; called by muse, mutect2, varscan2
- HOXB2 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57487733; called by muse, varscan2
- ISM1 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs768775917, COSV52606566; called by muse, mutect2, varscan2
- KCNH6 | c.2344G>A p.A782T | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV59005849; called by muse, mutect2, varscan2
- LURAP1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.182); catalogued as rs138211805, COSV64338391; called by muse, mutect2, varscan2
- MAST3 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV53224163; called by muse, mutect2
- MAST3 | c.2893C>T p.R965W | Missense Mutation (SNP) | VAF 33/217 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775231850, COSV53224177; called by muse, mutect2, varscan2
- MAST4 | c.2341G>A p.V781M (on ENST00000403625 / NM_001164664.2; = p.V592M on NM_015183.3) | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763416280, COSV55114987, COSV55117459; called by muse, mutect2, varscan2
- MX1 | c.1660A>C p.K554Q | Missense Mutation (SNP) | VAF 120/438 reads (27%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.732); catalogued as COSV55820166; called by muse, varscan2
- MYF5 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 61/209 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs1269683532, COSV57354981, COSV57355677; called by muse, mutect2, varscan2
- NECTIN4 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs756865692, COSV63513427; called by muse, mutect2
- NUP214 | c.3019G>A p.E1007K | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs767288782, COSV63911514; called by muse, mutect2, varscan2
- ODF3L1 | c.602C>A p.P201H | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59820324; called by muse, mutect2
- OR9A4 | c.123C>A p.N41K | Missense Mutation (SNP) | VAF 14/373 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1255239322, COSV71885775; called by muse, mutect2
- OXSR1 | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV61259695; called by muse, mutect2
- PCSK4 | c.2074C>T p.R692C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.183); catalogued as rs368826331, COSV56298303; called by muse, mutect2, varscan2
- PRRC2A | c.4147C>T p.R1383W | Missense Mutation (SNP) | VAF 39/235 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747020777, COSV65686156; called by muse, mutect2, varscan2
- RBFOX1 | c.1060G>A p.V354I | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.11); catalogued as rs138704494, COSV60951805; called by muse, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 18/178 reads (10%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RPTOR | c.1559C>T p.S520L | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs995035426, COSV60813647; called by muse, mutect2
- RWDD2A | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs779233613, COSV52285166; called by muse, mutect2, varscan2
- SCNN1B | c.1024A>G p.T342A | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV56307808; called by muse, mutect2
- SLC4A11 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs773524307, COSV66261726; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCA4 | c.2344G>A p.G782S | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100759205, COSV60801274; called by muse, mutect2, varscan2
- TACC1 | c.1816G>A p.V606M | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs775926435, COSV52526863; called by muse, mutect2, varscan2
- TBX18 | c.1691C>T p.T564M | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as rs1416893079, COSV63735937; called by muse, mutect2, varscan2
- TIAL1 | c.394A>G p.M132V | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.099); catalogued as COSV64843420; called by muse, mutect2, varscan2
- TMEM119 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.284); catalogued as rs373079326, COSV67188568, COSV67189022; called by muse, mutect2, varscan2
- TMLHE | c.905T>C p.I302T | Missense Mutation (SNP) | VAF 58/249 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as COSV57688443; called by muse, mutect2, varscan2
- TNS4 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs753848525, COSV54186895; called by muse, mutect2, varscan2
- TRPV6 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV63892156; called by muse, mutect2
- TTN | c.12341A>C p.N4114T (on ENST00000591111; = p.N4068T on NM_003319.4) | Missense Mutation (SNP) | VAF 34/165 reads (21%) | catalogued as COSV60208465; called by muse, mutect2, varscan2
- UGGT2 | c.1741C>T p.Q581* | Nonsense Mutation (SNP) | VAF 16/92 reads (17%) | catalogued as COSV65077134; called by muse, mutect2, varscan2
- UPF2 | c.3713G>A p.R1238H | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs1230421617, COSV62661724; called by muse, mutect2, varscan2
- UPK1B | c.732+3_732+6del p.X244_splice | Splice Site (DEL) | VAF 6/73 reads (8%) | catalogued as rs766558002; called by mutect2, pindel
- VCAN | c.2261C>A p.T754K | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV54108135, COSV99424941; called by muse, mutect2, varscan2
- XPNPEP2 | c.234+2T>G p.X78_splice | Splice Site (SNP) | VAF 37/184 reads (20%) | catalogued as COSV64368070; called by muse, mutect2, varscan2
- ZBTB46 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs569028644, COSV55511177, COSV99829393; called by muse, mutect2, varscan2
- AFF2 | c.3623+4_3623+7del p.X1208_splice | Splice Site (DEL) | VAF 16/105 reads (15%) | called by pindel, varscan2
- ARID2 | c.4621_4624del p.I1541Vfs*24 | Frame Shift Del (DEL) | VAF 23/79 reads (29%) | called by mutect2, pindel, varscan2
- BAG3 | c.546_551dup p.S184_S185dup | In Frame Ins (INS) | VAF 14/70 reads (20%) | called by mutect2, varscan2
- CHD4 | c.5608_5609del p.P1870Sfs*11 (on ENST00000357008 / NM_001363606.2; = p.P1880Sfs*11 on NM_001273.5) | Frame Shift Del (DEL) | VAF 98/467 reads (21%) | called by mutect2, pindel, varscan2
- EIF2AK3 | c.849del p.F283Lfs*23 | Frame Shift Del (DEL) | VAF 32/190 reads (17%) | called by mutect2, pindel, varscan2
- SOX9 | c.478dup p.R160Pfs*92 | Frame Shift Ins (INS) | VAF 11/33 reads (33%) | called by mutect2, pindel
- THSD1 | c.641_642del p.Y214Cfs*21 | Frame Shift Del (DEL) | VAF 15/79 reads (19%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.819T>C p.P273= | Silent (SNP) | VAF 20/208 reads (10%) | catalogued as COSV67990914; called by muse, mutect2
- BCL2L15 | c.52C>T p.L18= | Silent (SNP) | VAF 12/172 reads (7%) | catalogued as COSV63643164; called by muse, mutect2
- CRACDL | c.246G>A p.S82= | Silent (SNP) | VAF 29/195 reads (15%) | catalogued as rs201022444, COSV67409350; called by muse, mutect2, varscan2
- DLC1 | c.1050G>A p.A350= | Silent (SNP) | VAF 19/136 reads (14%) | catalogued as rs147228489, COSV52289800; called by muse, varscan2
- GALNT15 | c.522C>T p.P174= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs142412711; called by muse, mutect2, varscan2
- HIVEP1 | c.3009C>T p.P1003= | Silent (SNP) | VAF 40/240 reads (17%) | catalogued as rs199611604; called by muse, mutect2, varscan2
- ITGB7 | c.1776G>A p.T592= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs772827275, COSV57239573; called by mutect2, varscan2
- JRKL | c.342A>G p.G114= | Silent (SNP) | VAF 54/182 reads (30%) | catalogued as COSV53594539; called by muse, mutect2, varscan2
- MCPH1 | c.2481C>T p.A827= | Silent (SNP) | VAF 4/59 reads (7%) | catalogued as COSV60916937; called by muse, mutect2
- MPP4 | c.33A>C p.P11= | Silent (SNP) | VAF 38/605 reads (6%) | catalogued as COSV59632869; called by muse, mutect2
- NPAS3 | c.2544G>A p.A848= (on ENST00000356141 / NM_001164749.2; = p.A816= on NM_022123.3) | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1172676682, COSV60829635; called by muse, mutect2
- RAB24 | c.135C>T p.F45= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as rs777381025, COSV57463758, COSV99061617; called by mutect2, varscan2
- RIOK2 | c.1044C>T p.Y348= | Silent (SNP) | VAF 74/496 reads (15%) | catalogued as rs780015244, COSV51613984; called by muse, varscan2
- SEC13 | c.291C>T p.H97= (on ENST00000350697 / NM_183352.3; = p.H100= on NM_030673.4) | Silent (SNP) | VAF 44/154 reads (29%) | catalogued as rs376073337; called by muse, mutect2, varscan2
- SMS | c.465G>A p.S155= | Silent (SNP) | VAF 26/154 reads (17%) | catalogued as rs1261897927, COSV65114732; called by muse, mutect2, varscan2
- SON | c.138G>A p.A46= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as rs536267719, COSV51665328; called by muse, mutect2, varscan2
- SOX7 | c.858G>A p.P286= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs753879424, COSV58731297; called by muse, mutect2, varscan2
- TM9SF4 | c.1290A>G p.V430= | Silent (SNP) | VAF 14/146 reads (10%) | catalogued as COSV54109525; called by muse, mutect2
- UBQLNL | c.60G>T p.L20= | Silent (SNP) | VAF 40/138 reads (29%) | catalogued as rs766205549, COSV66494083; called by muse, mutect2, varscan2
- FAM27E5 | n.384C>T | RNA (SNP) | VAF 14/68 reads (21%) | catalogued as rs531957581; called by mutect2, varscan2
- GARRE1 | c.-2G>A | 5'UTR (SNP) | VAF 47/127 reads (37%) | catalogued as rs535765849, COSV100209119; called by muse, mutect2, varscan2
